Somatic mutation profile of tumor specimen MP2PRT-PAUNBP-TBP1-A (aliquot MP2PRT-PAUNBP-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUNBP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,496 days).
Specimen MP2PRT-PAUNBP-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce1e7a57-84a5-43c6-bbd0-800a11f84ff7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUNBP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUNBP-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ecc54dc-ee66-487e-acb6-91b56a4b299f

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL3 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 69/255 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as rs548026172; called by muse, mutect2, varscan2
- ITIH5 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs759497987, COSV56909484; called by muse, varscan2
- ZMIZ1 | c.883G>C p.A295P | Missense Mutation (SNP) | VAF 158/439 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as COSV57892513; called by muse, mutect2, varscan2
- SEC16A | c.5940G>A p.L1980= | Silent (SNP) | VAF 113/411 reads (27%) | catalogued as COSV51521830; called by muse, mutect2, varscan2
